CMI case MBCProject_3717 — CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/23bcc3ce-0c99-4ec3-83bf-e0f66b76bf39

Demographics
Sex at birth: female; Race: other; Ethnicity: not hispanic or latino.

Diagnoses (1)
1. Ductal carcinoma in situ, NOS: Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Age at diagnosis: 44.3 years (16,182 days).

Biospecimens (7 samples)
- Sample MBCProject_3717_SALIVA: Sample type: DNA; Tissue type: Normal; Specimen type: Saliva; Biospecimen anatomic site: Other.
- Samples MBCProject_3717_T1_RNA, MBCProject_3717_T1_WES (2 with the same recorded description): Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node(s) Cervical; Preservation method: FFPE.
- Samples MBCProject_3717_T2_RNA, MBCProject_3717_T2_WES, MBCProject_3717_T3_RNA, MBCProject_3717_T3_WES (4 with the same recorded description): Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node(s) Axilla; Preservation method: FFPE.
